Somatic mutation profile of tumor specimen BA3149D (aliquot aq-BA3149D) from BEATAML1.0 case 2597, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,122 days).
Specimen BA3149D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c615ce7e-7359-47fd-92d5-22a719a982f0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3316D (Solid Tissue Normal), aliquot aq-BA3316D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ad74893-73d4-4e5e-ac8e-83b1b33c582f

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDC4 | c.2992C>T p.H998Y | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs868529729; called by muse, mutect2
- PCDHA9 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); called by muse, mutect2
